Somatic mutation profile of tumor specimen C3L-02968-02 (aliquot CPT0196810009) from CPTAC case C3L-02968, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 64.8 years (23,682 days).
Specimen C3L-02968-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b1524f9-463c-4009-86e9-3152cb009af2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02968-31 (Blood Derived Normal), aliquot CPT0197760002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9010dba9-66ee-4eef-8538-befbb815a5ae

The open-access MAF lists 292 somatic variants for this specimen: 198 protein-altering or splice-affecting, 59 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 59, Intron 17, Nonsense Mutation 13, Frame Shift Del 8, Splice Site 6, RNA 5, 3'UTR 5, Splice Region 4, 5'UTR 4, 5'Flank 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHR | c.1160+1G>A p.X387_splice | Splice Site (SNP) | VAF 34/344 reads (10%) | catalogued as rs1562481438; ClinVar: pathogenic; called by muse, mutect2
- ADGRG4 | c.4910C>A p.P1637H | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV54965077; called by muse, mutect2, varscan2
- AFF2 | c.479C>G p.S160* | Nonsense Mutation (SNP) | VAF 28/129 reads (22%) | catalogued as COSV60660180; called by muse, mutect2, varscan2
- ALDH9A1 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 191/829 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs750893290; called by muse, mutect2, varscan2
- ARHGEF5 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 113/939 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs567758966; called by muse, mutect2, varscan2
- ATP1B4 | c.645G>T p.E215D (on ENST00000218008 / NM_001142447.3; = p.E211D on NM_012069.5) | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.903); catalogued as COSV54312718; called by muse, mutect2, varscan2
- ATP1B4 | c.646G>T p.D216Y (on ENST00000218008 / NM_001142447.3; = p.D212Y on NM_012069.5) | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV54311659; called by muse, mutect2, varscan2
- BDH1 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 101/475 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100827162, COSV64018654; called by muse, mutect2, varscan2
- C6orf118 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 128/396 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV57817327; called by muse, mutect2, varscan2
- CCDC80 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 68/735 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1216753978, COSV52819921; called by muse, mutect2
- CD1C | c.637C>A p.R213S | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV63807285; called by muse, mutect2
- CFC1 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 106/745 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV52090306, COSV99035000; called by muse, mutect2, varscan2
- COL22A1 | c.2700G>T p.P900= | Splice Region (SNP) | VAF 128/450 reads (28%) | catalogued as COSV100278875; called by muse, mutect2, varscan2
- CSMD3 | c.7612A>G p.I2538V (on ENST00000297405 / NM_001363185.1; = p.I2434V on NM_052900.3) | Missense Mutation (SNP) | VAF 100/347 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1336606618, COSV52094241; called by muse, mutect2, varscan2
- CSMD3 | c.7516G>A p.E2506K (on ENST00000297405 / NM_001363185.1; = p.E2402K on NM_052900.3) | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52100007, COSV99847343; called by muse, mutect2, varscan2
- DCN | c.569G>C p.G190A | Missense Mutation (SNP) | VAF 58/432 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50006788; called by muse, mutect2, varscan2
- DMRTA1 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 75/228 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1287902159; called by muse, mutect2, varscan2
- DNAH6 | c.3958-1G>T p.X1320_splice | Splice Site (SNP) | VAF 15/65 reads (23%) | catalogued as COSV99031466; called by muse, mutect2, varscan2
- DNAH6 | c.5019A>G p.I1673M | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99409245; called by muse, mutect2, varscan2
- DSCAM | c.5270C>A p.P1757H | Missense Mutation (SNP) | VAF 103/331 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68035857; called by muse, mutect2, varscan2
- ENAM | c.2407C>A p.Q803K | Missense Mutation (SNP) | VAF 176/547 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV101253346; called by muse, mutect2, varscan2
- FAM110A | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1431430155; called by muse, mutect2, varscan2
- FSIP2 | c.936C>G p.N312K | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100553781; called by muse, mutect2, varscan2
- GRIN2B | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 140/443 reads (32%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.568); catalogued as COSV101662857; called by muse, mutect2, varscan2
- IMPG1 | c.1399A>G p.T467A | Missense Mutation (SNP) | VAF 134/374 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV64061543; called by muse, mutect2, varscan2
- JPH3 | c.1235C>A p.A412D | Missense Mutation (SNP) | VAF 123/563 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52472764; called by muse, mutect2, varscan2
- KMT2D | c.7528G>A p.V2510I | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.098); catalogued as rs1565792744; called by muse, mutect2, varscan2
- LCAT | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 59/263 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM117831; called by muse, mutect2, varscan2
- LENG8 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 73/371 reads (20%) | catalogued as COSV58728946; called by muse, mutect2, varscan2
- LHCGR | c.1273C>A p.Q425K | Missense Mutation (SNP) | VAF 81/384 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as COSV99684014; called by muse, mutect2, varscan2
- MMRN1 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 73/278 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.115); catalogued as COSV53333389; called by muse, mutect2, varscan2
- MUC12 | c.4421A>G p.Q1474R (on ENST00000379442; = p.Q1331R on NM_001164462.1) | Missense Mutation (SNP) | VAF 288/1481 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.072); catalogued as rs1268434679, COSV65198041; called by muse, mutect2, varscan2
- NCKAP5L | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 71/276 reads (26%) | catalogued as COSV60130904; called by muse, mutect2, varscan2
- NETO1 | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1250730260, COSV55009406; called by muse, mutect2, varscan2
- NOTCH1 | c.5035G>T p.E1679* | Nonsense Mutation (SNP) | VAF 188/663 reads (28%) | catalogued as COSV53034857; called by muse, mutect2, varscan2
- OR10G9 | c.836C>A p.T279K | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV66685841; called by muse, mutect2
- OR10K1 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 126/588 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99193327; called by muse, mutect2, varscan2
- OR2D2 | c.191G>T p.C64F | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV55057731; called by muse, mutect2, varscan2
- OR4C13 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as rs528163289; called by muse, mutect2, varscan2
- OR4E2 | c.455del p.G152Vfs*6 | Frame Shift Del (DEL) | VAF 43/202 reads (21%) | catalogued as rs764448584, COSV100330146; called by mutect2, pindel, varscan2
- OR52E4 | c.759C>A p.Y253* | Nonsense Mutation (SNP) | VAF 32/133 reads (24%) | catalogued as COSV100389157; called by muse, mutect2, varscan2
- PAPPA2 | c.4604A>T p.N1535I | Missense Mutation (SNP) | VAF 194/850 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV62797062; called by muse, mutect2, varscan2
- PCDHGA1 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 143/533 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs754685144, COSV65297868; called by mutect2, varscan2
- PHF21B | c.1421G>T p.G474V | Missense Mutation (SNP) | VAF 57/488 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs777340651; called by muse, mutect2, varscan2
- PNLIP | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779338098, COSV65039745; called by muse, mutect2, varscan2
- PRAMEF2 | c.317G>T p.R106L | Missense Mutation (SNP) | VAF 90/559 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs781570449; called by muse, mutect2, varscan2
- PRPF6 | c.950G>T p.R317L | Missense Mutation (SNP) | VAF 168/720 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99412595; called by muse, mutect2, varscan2
- PTGES2 | c.488A>G p.N163S | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs755024661; called by muse, mutect2, varscan2
- RELN | c.2902C>A p.L968I | Missense Mutation (SNP) | VAF 101/626 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.108); catalogued as COSV100635047; called by muse, mutect2, varscan2
- RET | c.110G>T p.W37L | Missense Mutation (SNP) | VAF 83/537 reads (15%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.007); catalogued as BM1214459, COSV60702463; called by muse, mutect2, varscan2
- REV3L | c.1073A>G p.H358R | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs754380930; called by muse, mutect2, varscan2
- RYR3 | c.1149C>A p.V383= | Splice Region (SNP) | VAF 77/219 reads (35%) | catalogued as COSV66810831; called by muse, mutect2, varscan2
- SLC35F6 | c.9G>C p.W3C | Missense Mutation (SNP) | VAF 201/710 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60427088; called by muse, mutect2, varscan2
- SPATA31E1 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs201798562; called by muse, mutect2, varscan2
- SYNCRIP | c.1636A>G p.R546G | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs753422712; called by muse, mutect2, varscan2
- TEX13C | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV101359839; called by muse, mutect2, varscan2
- THSD7A | c.1701del p.C568Vfs*12 | Frame Shift Del (DEL) | VAF 86/461 reads (19%) | catalogued as COSV70264112; called by mutect2, pindel, varscan2
- TICRR | c.4720C>T p.R1574* | Nonsense Mutation (SNP) | VAF 80/289 reads (28%) | catalogued as rs1302873022, COSV51538579; called by muse, mutect2, varscan2
- TMX3 | c.319G>T p.G107W | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55184921; called by muse, mutect2, varscan2
- TREML4 | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV58385543; called by muse, mutect2, varscan2
- TRIM68 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56168680; called by muse, mutect2, varscan2
- UGGT2 | c.2579G>A p.C860Y | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100948489; called by muse, mutect2, varscan2
- UNC13C | c.4307G>C p.G1436A | Missense Mutation (SNP) | VAF 115/438 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.705); catalogued as rs772589057, COSV52915191; called by muse, mutect2, varscan2
- ZEB2 | c.3244A>T p.K1082* | Nonsense Mutation (SNP) | VAF 52/159 reads (33%) | catalogued as COSV100356612; called by muse, mutect2, varscan2
- ABCA13 | c.11602G>A p.D3868N | Missense Mutation (SNP) | VAF 82/417 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ABCB4 | c.2249dup p.C751Vfs*43 | Frame Shift Ins (INS) | VAF 84/461 reads (18%) | called by mutect2, pindel, varscan2
- ADCYAP1R1 | c.1058G>T p.R353L | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ADGRA1 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- AIFM3 | c.1219-7C>T | Splice Region (SNP) | VAF 109/518 reads (21%) | called by muse, mutect2, varscan2
- ANKS1B | c.2831del p.G944Efs*45 (on ENST00000547776 / NM_152788.4; = p.G170Efs*64 on NM_020140.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 51/214 reads (24%) | called by mutect2, pindel, varscan2
- ANKS3 | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANPEP | c.2846A>G p.K949R | Missense Mutation (SNP) | VAF 63/502 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ARL5B | c.399G>C p.M133I | Missense Mutation (SNP) | VAF 20/261 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2
- ATP8B4 | c.2815C>A p.Q939K | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BICDL1 | c.1006A>T p.S336C | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- BIN1 | c.745G>T p.E249* (on ENST00000316724 / NM_001320642.1; = p.E218* on NM_004305.4) | Nonsense Mutation (SNP) | VAF 106/445 reads (24%) | called by muse, mutect2, varscan2
- C17orf80 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 103/534 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- C19orf84 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 96/484 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CACNG5 | c.614C>A p.T205N | Missense Mutation (SNP) | VAF 527/952 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CALB1 | c.507-1G>T p.X169_splice | Splice Site (SNP) | VAF 31/152 reads (20%) | called by muse, mutect2, varscan2
- CCDC178 | c.1767A>C p.Q589H | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- CCDC87 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC91 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- CCNB3 | c.1408G>T p.A470S | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD200 | c.288C>A p.S96R (on ENST00000473539 / NM_001004196.3; = p.S71R on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/563 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CDC14C | c.835C>T p.L279F (on ENST00000428251; = p.L172F on NM_152627.3) | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- CDK13 | c.2615A>T p.N872I | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLMN | c.985_994del p.T329Gfs*28 | Frame Shift Del (DEL) | VAF 54/366 reads (15%) | called by mutect2, pindel, varscan2
- CPXM2 | c.159G>C p.E53D | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRACD | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUL3 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- CYP11A1 | c.1070T>C p.L357S | Missense Mutation (SNP) | VAF 133/569 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DMD | c.1876G>C p.D626H | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DOCK4 | c.958C>T p.L320F | Missense Mutation (SNP) | VAF 76/286 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPH1 | c.59G>C p.R20T | Missense Mutation (SNP) | VAF 83/281 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DPY19L3 | c.1901A>T p.Y634F | Missense Mutation (SNP) | VAF 72/348 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ECPAS | c.4470G>T p.E1490D | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ENTPD1 | c.1424C>G p.S475C | Missense Mutation (SNP) | VAF 92/678 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- ESF1 | c.354G>C p.K118N | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM205A | c.1352C>A p.S451Y | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- FASTKD2 | c.1970T>A p.M657K | Missense Mutation (SNP) | VAF 59/456 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- FLCN | c.494dup p.F166Lfs*34 | Frame Shift Ins (INS) | VAF 200/752 reads (27%) | called by mutect2, pindel, varscan2
- FMN2 | c.2645C>T p.P882L | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FOXL1 | c.447del p.A151Pfs*113 | Frame Shift Del (DEL) | VAF 144/778 reads (19%) | called by pindel, varscan2
- GABPB2 | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GAP43 | c.107C>G p.T36S | Missense Mutation (SNP) | VAF 74/310 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- GBP1 | c.721C>G p.P241A | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1939G>T p.A647S | Missense Mutation (SNP) | VAF 98/910 reads (11%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- HACD1 | c.94A>G p.T32A | Missense Mutation (SNP) | VAF 57/363 reads (16%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDX | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- HHLA1 | c.743G>C p.S248T | Missense Mutation (SNP) | VAF 145/436 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- HTRA4 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 117/873 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ICAM2 | c.520A>C p.T174P | Missense Mutation (SNP) | VAF 650/1072 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- IFT80 | c.991C>G p.L331V | Missense Mutation (SNP) | VAF 48/514 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); called by muse, mutect2
- IGFN1 | c.185G>T p.W62L | Missense Mutation (SNP) | VAF 46/390 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV1-5 | c.6C>G p.D2E | Missense Mutation (SNP) | VAF 104/579 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- IGLJ7 | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 63/343 reads (18%) | called by muse, mutect2, varscan2
- INPPL1 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.867); called by muse, mutect2
- INTS8 | c.1119-2A>G p.X373_splice | Splice Site (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- KIAA0753 | c.586C>G p.P196A | Missense Mutation (SNP) | VAF 107/390 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- KPTN | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 79/392 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- KRBA1 | c.2350_2367del p.L784_L789del | In Frame Del (DEL) | VAF 88/609 reads (14%) | called by mutect2, pindel, varscan2
- KRTAP10-7 | c.638G>T p.S213I | Missense Mutation (SNP) | VAF 282/961 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- LCE2A | c.70T>A p.C24S | Missense Mutation (SNP) | VAF 107/457 reads (23%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- LRP1B | c.1595C>A p.P532Q | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC4C | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- LRRC7 | c.4433T>C p.M1478T (on ENST00000651989 / NM_001370785.2; = p.M1398T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRK2 | c.1395G>T p.M465I | Missense Mutation (SNP) | VAF 56/281 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRN3 | c.2048T>C p.L683P | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- MDM4 | c.903G>A p.E301= | Splice Region (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- MYH2 | c.2993T>A p.L998Q | Missense Mutation (SNP) | VAF 182/634 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- NAALAD2 | c.1505T>C p.I502T | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- NCCRP1 | c.724C>A p.R242S | Missense Mutation (SNP) | VAF 90/476 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- NELL1 | c.791T>A p.L264* | Nonsense Mutation (SNP) | VAF 22/196 reads (11%) | called by muse, mutect2, varscan2
- NPBWR2 | c.920C>A p.A307D | Missense Mutation (SNP) | VAF 56/260 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- NR1D1 | c.1667C>A p.S556Y | Missense Mutation (SNP) | VAF 58/698 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- NR5A1 | c.1133G>T p.S378I | Missense Mutation (SNP) | VAF 73/340 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- NUP98 | c.4439A>T p.E1480V (on ENST00000359171 / NM_001365126.1; = p.E1463V on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 129/562 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- NYX | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OAS1 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 70/481 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OR13C8 | c.176T>A p.M59K | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PCDHB14 | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHF20L1 | c.2048G>T p.R683L | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PJA1 | c.913del p.A305Qfs*29 (on ENST00000361478 / NM_145119.4; = p.A117Qfs*29 on NM_022368.5) | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | called by mutect2, pindel, varscan2
- PLCB1 | c.1019T>A p.L340Q | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCB4 | c.2796A>C p.L932F | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.334); called by muse, mutect2
- PRAME | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 102/566 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRDM2 | c.497C>G p.P166R | Missense Mutation (SNP) | VAF 163/538 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PTGIS | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 89/408 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- RAB11FIP4 | c.1532A>T p.Q511L | Missense Mutation (SNP) | VAF 79/272 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- RAD51AP2 | c.2433A>G p.I811M | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- RALGAPA1 | c.2461C>A p.L821M | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RASA1 | c.630del p.R211Gfs*14 | Frame Shift Del (DEL) | VAF 81/368 reads (22%) | called by mutect2, pindel, varscan2
- RFLNA | c.634G>T p.G212C (on ENST00000546355 / NM_001365156.1; = p.G131C on NM_181709.4) | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGS3 | c.2731A>T p.S911C (on ENST00000350696 / NM_001282923.2; = p.S630C on NM_130795.4) | Missense Mutation (SNP) | VAF 167/585 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- ROS1 | c.2630C>A p.A877D | Missense Mutation (SNP) | VAF 133/341 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- RXFP2 | c.1946T>A p.I649N | Missense Mutation (SNP) | VAF 54/415 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- RYR2 | c.12422G>C p.S4141T | Missense Mutation (SNP) | VAF 67/278 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- SACS | c.20+2T>A p.X7_splice | Splice Site (SNP) | VAF 31/229 reads (14%) | called by muse, mutect2, varscan2
- SAMD3 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 86/237 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SATL1 | c.610G>T p.G204W (on ENST00000395409; = p.G391W on NM_001012980.2) | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- SI | c.1049A>T p.Y350F | Missense Mutation (SNP) | VAF 74/367 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SI | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 41/295 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- SIGLEC8 | c.1154G>C p.R385T | Missense Mutation (SNP) | VAF 102/652 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- SLC39A6 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 99/528 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC4A8 | c.1709C>A p.T570N | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- SLC4A8 | c.2294G>T p.R765M | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- SLITRK3 | c.1451A>T p.Y484F | Missense Mutation (SNP) | VAF 78/331 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SNTG1 | c.1331A>T p.D444V | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SNX16 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SORCS1 | c.3334G>T p.V1112L | Missense Mutation (SNP) | VAF 55/483 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SORCS1 | c.1753G>C p.E585Q | Missense Mutation (SNP) | VAF 49/243 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SSU72P8 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TAAR8 | c.476C>A p.P159H | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TDRD3 | c.1765G>C p.V589L | Missense Mutation (SNP) | VAF 30/349 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.295); called by muse, mutect2
- TEKT4 | c.1094T>A p.L365Q | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TEX15 | c.6740C>A p.A2247D (on ENST00000256246; = p.A2630D on NM_001350162.2) | Missense Mutation (SNP) | VAF 51/220 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TLN2 | c.5710G>A p.A1904T | Missense Mutation (SNP) | VAF 79/326 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMX3 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TNKS | c.2348G>T p.G783V | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TP53 | c.270del p.W91Gfs*32 | Frame Shift Del (DEL) | VAF 81/293 reads (28%) | called by mutect2, pindel, varscan2
- TRAV6 | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 71/317 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- TRGV1 | c.41C>G p.P14R | Missense Mutation (SNP) | VAF 133/674 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TRIM24 | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TRIM51GP | c.1110G>T p.M370I | Missense Mutation (SNP) | VAF 153/530 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC8 | c.1075G>T p.E359* (on ENST00000338104 / NM_001288781.1; = p.E343* on NM_144596.4) | Nonsense Mutation (SNP) | VAF 54/537 reads (10%) | called by muse, mutect2, varscan2
- TTN | c.47858C>A p.A15953D (on ENST00000591111; = p.A8529D on NM_003319.4) | Missense Mutation (SNP) | VAF 69/560 reads (12%) | PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- TTN | c.23665A>T p.K7889* (on ENST00000591111; = p.K6962* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/223 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.12685T>C p.Y4229H (on ENST00000591111; = p.Y4183H on NM_003319.4) | Missense Mutation (SNP) | VAF 75/260 reads (29%) | called by muse, mutect2, varscan2
- UGT3A2 | c.1063A>T p.S355C | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ULK4 | c.1348+2T>G p.X450_splice | Splice Site (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- UPF2 | c.2596C>T p.Q866* | Nonsense Mutation (SNP) | VAF 26/96 reads (27%) | called by muse, mutect2, varscan2
- USP13 | c.1445A>T p.Q482L | Missense Mutation (SNP) | VAF 107/877 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- USP40 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 54/466 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- VSIG4 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZIC3 | c.291C>A p.H97Q | Missense Mutation (SNP) | VAF 74/281 reads (26%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF716 | c.588G>C p.M196I | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF735 | c.448T>A p.S150T | Missense Mutation (SNP) | VAF 59/332 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ADAMTS12 | c.3138A>T p.P1046= | Silent (SNP) | VAF 16/304 reads (5%) | called by muse, mutect2
- ADCY1 | c.939G>T p.T313= | Silent (SNP) | VAF 87/455 reads (19%) | catalogued as COSV52031301, COSV52034722; called by muse, mutect2, varscan2
- AMER3 | c.2358A>G p.A786= | Silent (SNP) | VAF 89/386 reads (23%) | called by muse, mutect2, varscan2
- BRINP2 | c.438C>T p.F146= | Silent (SNP) | VAF 20/178 reads (11%) | called by muse, mutect2, varscan2
- CA5A | c.187C>A p.R63= | Silent (SNP) | VAF 54/306 reads (18%) | called by muse, mutect2, varscan2
- CR2 | c.31T>C p.L11= | Silent (SNP) | VAF 78/272 reads (29%) | called by muse, mutect2, varscan2
- DENND4A | c.1341G>T p.P447= | Silent (SNP) | VAF 51/184 reads (28%) | called by muse, mutect2, varscan2
- DHX37 | c.783C>T p.I261= | Silent (SNP) | VAF 22/192 reads (11%) | called by muse, mutect2, varscan2
- DNAJC5G | c.225C>T p.F75= | Silent (SNP) | VAF 170/869 reads (20%) | catalogued as COSV56081351, COSV56081643; called by muse, mutect2, varscan2
- DPEP1 | c.312G>T p.V104= | Silent (SNP) | VAF 132/598 reads (22%) | called by muse, mutect2, varscan2
- DPY30 | c.204A>G p.G68= | Silent (SNP) | VAF 57/232 reads (25%) | called by muse, mutect2, varscan2
- EP300 | c.6240G>T p.L2080= | Silent (SNP) | VAF 133/920 reads (14%) | called by muse, mutect2, varscan2
- EPRS1 | c.1491A>G p.K497= | Silent (SNP) | VAF 44/342 reads (13%) | called by muse, mutect2, varscan2
- ERCC6L2 | c.1941C>T p.Y647= | Silent (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- EVX1 | c.885C>A p.A295= | Silent (SNP) | VAF 143/594 reads (24%) | called by muse, mutect2, varscan2
- FANCL | c.6G>T p.A2= | Silent (SNP) | VAF 262/1096 reads (24%) | called by muse, mutect2, varscan2
- FCGR2B | c.588C>T p.C196= | Silent (SNP) | VAF 69/464 reads (15%) | called by muse, mutect2, varscan2
- GCLC | c.1326C>T p.A442= (on ENST00000643939; = p.A440= on NM_001498.4) | Silent (SNP) | VAF 173/446 reads (39%) | called by muse, mutect2, varscan2
- GJA8 | c.159G>C p.V53= | Silent (SNP) | VAF 127/537 reads (24%) | called by muse, mutect2, varscan2
- GSTM5 | c.30C>A p.I10= | Silent (SNP) | VAF 130/471 reads (28%) | catalogued as COSV99859433; called by muse, mutect2, varscan2
- H3-3A | c.225T>A p.I75= | Silent (SNP) | VAF 28/259 reads (11%) | called by muse, mutect2, varscan2
- IQGAP3 | c.1104C>T p.N368= | Silent (SNP) | VAF 48/224 reads (21%) | called by muse, mutect2, varscan2
- ITGB2 | c.1215C>G p.T405= (on ENST00000302347; = p.T381= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 222/732 reads (30%) | catalogued as CD109173, COSV56612379; called by muse, mutect2, varscan2
- KCNH7 | c.3081C>A p.T1027= | Silent (SNP) | VAF 107/353 reads (30%) | called by muse, mutect2, varscan2
- KCNJ5 | c.1128C>T p.L376= | Silent (SNP) | VAF 93/324 reads (29%) | called by muse, mutect2, varscan2
- KLHL14 | c.1413G>T p.G471= | Silent (SNP) | VAF 49/216 reads (23%) | catalogued as COSV63831936; called by muse, mutect2, varscan2
- KREMEN2 | c.594C>T p.H198= | Silent (SNP) | VAF 82/825 reads (10%) | catalogued as rs1331390817; called by muse, mutect2, varscan2
- LRRK2 | c.6402A>T p.S2134= | Silent (SNP) | VAF 40/234 reads (17%) | called by muse, mutect2, varscan2
- MAPKAPK2 | c.1188G>A p.A396= | Silent (SNP) | VAF 27/188 reads (14%) | catalogued as rs201580623; called by muse, mutect2, varscan2
- MLXIPL | c.54G>C p.A18= | Silent (SNP) | VAF 88/349 reads (25%) | called by muse, mutect2, varscan2
- MTNR1B | c.105A>T p.R35= | Silent (SNP) | VAF 77/294 reads (26%) | called by muse, mutect2, varscan2
- NAGK | c.399C>T p.L133= | Silent (SNP) | VAF 51/612 reads (8%) | catalogued as rs750993817; called by muse, mutect2
- NLRP11 | c.1341G>A p.K447= | Silent (SNP) | VAF 35/141 reads (25%) | called by muse, mutect2, varscan2
- NOS1 | c.3240C>A p.V1080= | Silent (SNP) | VAF 32/225 reads (14%) | called by muse, mutect2, varscan2
- NOTCH1 | c.5034G>T p.L1678= | Silent (SNP) | VAF 188/664 reads (28%) | called by muse, mutect2, varscan2
- NPBWR2 | c.921C>A p.A307= | Silent (SNP) | VAF 54/257 reads (21%) | called by muse, mutect2, varscan2
- NUTM2F | c.1314G>A p.P438= | Silent (SNP) | VAF 73/530 reads (14%) | catalogued as rs1211142726; called by muse, mutect2, varscan2
- NXPH1 | c.810G>T p.S270= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV101339573, COSV68313546; called by muse, mutect2, varscan2
- OR2C3 | c.249G>A p.L83= | Silent (SNP) | VAF 114/497 reads (23%) | catalogued as COSV63575216; called by muse, mutect2, varscan2
- OR2M4 | c.174C>T p.P58= | Silent (SNP) | VAF 41/147 reads (28%) | catalogued as COSV60708379; called by muse, mutect2, varscan2
- OR52N2 | c.465G>A p.V155= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV57676643; called by muse, mutect2, varscan2
- PCDHGA7 | c.921A>G p.L307= | Silent (SNP) | VAF 49/171 reads (29%) | catalogued as COSV99532747; called by muse, mutect2, varscan2
- PDZD2 | c.748C>T p.L250= | Silent (SNP) | VAF 140/731 reads (19%) | called by muse, mutect2, varscan2
- PGF | c.363G>T p.T121= | Silent (SNP) | VAF 36/183 reads (20%) | catalogued as COSV53124615; called by muse, mutect2, varscan2
- PKD1L1 | c.8070G>A p.L2690= | Silent (SNP) | VAF 170/778 reads (22%) | catalogued as rs753572403; called by muse, mutect2, varscan2
- POSTN | c.1428G>A p.G476= | Silent (SNP) | VAF 51/392 reads (13%) | called by muse, mutect2, varscan2
- PRAMEF2 | c.318G>T p.R106= | Silent (SNP) | VAF 94/567 reads (17%) | called by muse, mutect2, varscan2
- PRAMEF20 | c.279T>A p.V93= | Silent (SNP) | VAF 254/857 reads (30%) | called by muse, mutect2, varscan2
- RNF17 | c.2037T>C p.D679= | Silent (SNP) | VAF 28/199 reads (14%) | called by muse, mutect2, varscan2
- SLC7A3 | c.1740C>A p.I580= | Silent (SNP) | VAF 34/101 reads (34%) | called by muse, mutect2, varscan2
- SPATA6 | c.709C>T p.L237= | Silent (SNP) | VAF 96/366 reads (26%) | called by muse, mutect2, varscan2
- TENM1 | c.870C>A p.P290= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as COSV100950167; called by muse, mutect2, varscan2
- THSD7A | c.1842G>A p.Q614= | Silent (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2, varscan2
- TMEM63B | c.21C>T p.A7= | Silent (SNP) | VAF 27/220 reads (12%) | called by muse, mutect2, varscan2
- TRIM66 | c.225G>T p.L75= | Silent (SNP) | VAF 106/469 reads (23%) | catalogued as rs1420888637; called by muse, mutect2, varscan2
- USP35 | c.696C>T p.A232= | Silent (SNP) | VAF 32/243 reads (13%) | catalogued as COSV71572927; called by muse, mutect2, varscan2
- WARS1 | c.21A>G p.A7= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs772761404; called by muse, mutect2, varscan2
- WDR5 | c.648C>A p.P216= | Silent (SNP) | VAF 115/333 reads (35%) | catalogued as rs775415499, COSV62272976, COSV62273253; called by muse, mutect2, varscan2
- XKR4 | c.747C>T p.S249= | Silent (SNP) | VAF 56/294 reads (19%) | called by muse, mutect2, varscan2
- ANKRD13D | c.*468G>C | 3'UTR (SNP) | VAF 139/505 reads (28%) | catalogued as COSV57752703; called by muse, mutect2, varscan2
- BRD8 | c.-1G>T | 5'UTR (SNP) | VAF 99/447 reads (22%) | called by muse, mutect2, varscan2
- C22orf34 | n.448C>A | RNA (SNP) | VAF 22/140 reads (16%) | called by muse, varscan2
- CALY | c.246+102C>A | Intron (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- CBLN1 | c.265-75G>T | Intron (SNP) | VAF 116/473 reads (25%) | called by muse, mutect2, varscan2
- CDKN1C | c.821-53C>T | Intron (SNP) | VAF 16/90 reads (18%) | catalogued as rs1452111867; called by muse, mutect2, varscan2
- DPYSL2 | chr8:26577119 C>G | 5'Flank (SNP) | VAF 25/387 reads (6%) | called by muse, mutect2
- DST | c.4296+4505G>T | Intron (SNP) | VAF 131/341 reads (38%) | called by muse, mutect2, varscan2
- FCHO1 | c.1183-20G>A | Intron (SNP) | VAF 128/332 reads (39%) | called by muse, mutect2, varscan2
- GRAMD1B | c.24-16740T>C | Intron (SNP) | VAF 61/319 reads (19%) | called by muse, varscan2
- GRM7 | c.2452-43772G>T | Intron (SNP) | VAF 33/172 reads (19%) | catalogued as rs1328300828; called by muse, mutect2, varscan2
- GUSBP4 | n.56G>T | RNA (SNP) | VAF 74/286 reads (26%) | called by muse, mutect2, varscan2
- HDAC4 | c.2373+10G>T | Intron (SNP) | VAF 62/466 reads (13%) | called by muse, mutect2, varscan2
- HMGA2 | c.249+43318C>A | Intron (SNP) | VAF 87/345 reads (25%) | called by muse, mutect2, varscan2
- IL10RA | c.*749G>A | 3'UTR (SNP) | VAF 110/408 reads (27%) | called by muse, mutect2, varscan2
- KCNJ8 | c.-27G>C | 5'UTR (SNP) | VAF 77/426 reads (18%) | called by muse, mutect2, varscan2
- LINC01644 | n.525A>G | RNA (SNP) | VAF 19/132 reads (14%) | called by muse, mutect2, varscan2
- MARCHF1 | c.424-10189C>A | Intron (SNP) | VAF 50/199 reads (25%) | catalogued as rs771803906; called by muse, mutect2, varscan2
- MORF4 | n.698A>G | RNA (SNP) | VAF 72/288 reads (25%) | called by muse, mutect2, varscan2
- NDUFAF5 | c.863-37G>A | Intron (SNP) | VAF 32/186 reads (17%) | called by muse, mutect2, varscan2
- PSG5 | c.431-2937C>T | Intron (SNP) | VAF 69/493 reads (14%) | catalogued as rs756292700; called by muse, mutect2, varscan2
- PSG6 | c.706+65G>A | Intron (SNP) | VAF 98/468 reads (21%) | catalogued as rs758633006; called by muse, mutect2, varscan2
- PSG6 | c.706+64G>C | Intron (SNP) | VAF 102/477 reads (21%) | called by muse, mutect2, varscan2
- PTPN20CP | n.644A>T | RNA (SNP) | VAF 44/537 reads (8%) | called by muse, mutect2
- RAB26 | c.*312T>C | 3'UTR (SNP) | VAF 122/463 reads (26%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159500 C>A | 5'Flank (SNP) | VAF 20/69 reads (29%) | catalogued as rs776552858; called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159666 C>A | 5'Flank (SNP) | VAF 54/251 reads (22%) | called by muse, mutect2, varscan2
- RPAIN | c.-128G>T | 5'UTR (SNP) | VAF 91/262 reads (35%) | catalogued as rs531434955; called by muse, mutect2, varscan2
- SLC4A8 | c.131-35G>T | Intron (SNP) | VAF 55/257 reads (21%) | called by muse, mutect2, varscan2
- SNRNP27 | c.-2A>G | 5'UTR (SNP) | VAF 113/522 reads (22%) | catalogued as rs781555809; called by muse, mutect2, varscan2
- SORBS3 | c.*257G>A | 3'UTR (SNP) | VAF 23/89 reads (26%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-2662A>T | Intron (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- SSUH2 | c.-3-483G>T | Intron (SNP) | VAF 65/207 reads (31%) | called by muse, mutect2, varscan2
- SYT14 | chr1:210162995 G>T | 3'Flank (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- VWA7 | c.*1C>T | 3'UTR (SNP) | VAF 153/373 reads (41%) | called by muse, mutect2, varscan2
